Gene-level copy-number profile of tumor specimen ALCH-B3FT-TTP1-A from ALCHEMIST case ALCH-B3FT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.8 years (24,414 days).
Specimen ALCH-B3FT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f106fc00-0075-4d51-ae38-4b45cb019c68.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,273 have no estimate.
https://portal.gdc.cancer.gov/files/8d8016bf-fcca-4bee-91c9-635ebc32f3f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 144; copy number 1: 2,563; copy number 2: 52,025; copy number 3: 2,835; copy number 4: 533; copy number 5: 70; copy number 6: 35; copy number 7: 88; copy number 8: 9; copy number 9: 11; copy number 10: 4; copy number 11: 4; copy number 12: 5; copy number 13: 3; copy number 14: 7; copy number 15: 6; copy number 17: 1; copy number 20: 1; copy number 22: 5; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 132 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,208,136–62,211,666, 2 genes (within-gene range 0–1): AL162739.1, Y_RNA.
- chr2:25,160,853–25,168,903, 1 gene: POMC.
- chr2:90,179,889–90,315,836, 7 genes: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118.
- chr2:91,578,478–91,580,863, 2 genes: AC233266.1, AC233266.2.
- chr2:91,617,160–91,723,605, 5 genes (within-gene range 0–1): LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2.
- chr2:241,551,424–241,574,131, 1 gene (within-gene range 0–2): BOK.
- chr2:241,800,916–241,801,907, 1 gene (within-gene range 0–1): AC131097.1.
- chr3:57,060,664–57,080,101, 2 genes (within-gene range 0–2): SPATA12, AC097358.2.
- chr3:75,415,070–75,435,110, 2 genes: ALG1L6P, FAM86DP.
- chr3:75,598,652–75,623,849, 2 genes: OR7E121P, UNC93B3.
- chr4:9,692,495–9,710,812, 2 genes: FAM86MP, ALG1L3P.
- chr4:49,588,772–49,589,529, 1 gene: SNX18P25.
- chr5:466,124–473,098, 1 gene (within-gene range 0–4): PP7080.
- chr5:138,454,540–138,469,303, 2 genes: AC113403.1, EGR1.
- chr5:176,620,082–176,630,556, 2 genes: SNCB, MIR4281.
- chr5:181,043,403–181,043,484, 1 gene (within-gene range 0–1): MIR8089.
- chr7:4,811,188–4,811,289, 1 gene (within-gene range 0–1): Y_RNA.
- chr7:5,495,819–5,495,917, 1 gene (within-gene range 0–1): MIR589.
- chr7:6,490,793–6,491,098, 1 gene: AC072052.1.
- chr7:6,710,128–6,799,365, 3 genes (within-gene range 0–1): PMS2CL, SPDYE20P, RSPH10B2.
- chr7:56,340,231–56,381,312, 4 genes: RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2.
- chr7:57,209,865–57,227,066, 2 genes: AC099654.1, RNU7-157P.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–1): AP001271.2.
- chr11:70,646,165–70,706,068, 3 genes (within-gene range 0–1): SHANK2-AS2, Y_RNA, AP000590.1.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr14:105,597,691–105,601,728, 1 gene (within-gene range 0–7): IGHE.
- chr14:106,770,577–106,771,020, 1 gene: IGHV2-70.
- chr16:1,751,559–1,752,262, 1 gene (within-gene range 0–5): AL031717.1.
- chr16:1,911,475–1,918,415, 1 gene: HS3ST6.
- chr16:2,009,926–2,020,755, 2 genes: NPW, RN7SL219P.
- chr16:90,004,871–90,044,975, 3 genes (within-gene range 0–2): DBNDD1, GAS8, GAS8-AS1.
- chr17:3,721,628–3,730,493, 3 genes (within-gene range 0–1): AC116914.2, HASPIN, AC116914.1.
- chr19:1,505,022–1,513,604, 1 gene: ADAMTSL5.
- chr19:1,508,375–1,508,963, 1 gene: AC027307.1.
- chr19:24,004,358–24,004,507, 1 gene: RNA5-8SP4.
- chr20:63,547,891–63,556,695, 1 gene: FNDC11.
- chr21:7,744,962–9,376,645, 45 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2.
- chr21:13,038,160–13,067,033, 2 genes: ANKRD30BP2, RNU6-614P.
- chr22:18,077,920–18,177,397, 7 genes (within-gene range 0–1): PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18.
- chr22:50,199,090–50,200,837, 1 gene (within-gene range 0–8): AL022328.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 250 genes in 79 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,173,880–1,206,592, 2 genes, copy number 5 (within-gene range 4–5): TTLL10, TNFRSF18.
- chr1:1,242,446–1,251,334, 2 genes, copy number 6–17: C1QTNF12, AL162741.1.
- chr1:1,292,390–1,309,609, 2 genes, copy number 6 (within-gene range 2–6): ACAP3, MIR6726.
- chr1:1,324,756–1,361,777, 5 genes, copy number 5–11 (within-gene range 5–26): CPTP, TAS1R3, DVL1, MIR6808, MXRA8.
- chr1:1,401,909–1,442,882, 8 genes, copy number 6–8 (within-gene range 4–8): MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1, TMEM88B, LINC01770, VWA1.
- chr1:1,512,162–1,540,624, 2 genes, copy number 5–9: ATAD3A, TMEM240.
- chr1:1,915,108–1,919,279, 2 genes, copy number 5: CALML6, TMEM52.
- chr1:2,425,980–2,505,532, 3 genes, copy number 5: PLCH2, AL139246.1, AL139246.4.
- chr1:12,938,472–13,032,130, 2 genes, copy number 9 (within-gene range 2–9): PRAMEF6, PRAMEF28P.
- chr2:64,522,187–64,593,005, 4 genes, copy number 5: AC008074.2, AFTPH, MIR4434, RNU6-100P.
- chr3:183,613,620–183,684,519, 2 genes, copy number 5: AC068769.1, KLHL24.
- chr3:187,932,764–188,003,990, 4 genes, copy number 5: AC068295.1, LINC01991, AC092941.1, AC092941.2.
- chr3:188,562,238–188,688,866, 2 genes, copy number 5: LPP-AS1, MIR28.
- chr4:1,113,639–1,153,726, 3 genes, copy number 5 (within-gene range 3–5): AC092535.4, TMED11P, AC092535.1.
- chr5:795,606–919,357, 5 genes, copy number 5–6 (within-gene range 5–7): ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3.
- chr7:102,537,918–102,616,756, 6 genes, copy number 5–14 (within-gene range 4–14): POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4.
- chr8:142,784,882–142,812,120, 3 genes, copy number 5: LY6D, AC083841.2, AC083841.4.
- chr8:143,566,192–143,578,649, 3 genes, copy number 7–22 (within-gene range 2–22): MROH6, AC067930.4, NAPRT.
- chr9:136,754,386–136,800,595, 5 genes, copy number 5–12 (within-gene range 1–12): LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3.
- chr9:136,844,415–136,860,799, 3 genes, copy number 9 (within-gene range 4–14): AJM1, PHPT1, MAMDC4.
- chr9:137,007,234–137,040,436, 4 genes, copy number 6–13 (within-gene range 0–15): ABCA2, C9orf139, FUT7, AL807752.6.
- chr9:137,048,107–137,054,061, 2 genes, copy number 7: ENTPD2, AL807752.4.
- chr11:694,438–727,727, 2 genes, copy number 6 (within-gene range 2–6): EPS8L2, TMEM80.
- chr11:779,617–809,753, 5 genes, copy number 6–12 (within-gene range 3–12): AP006621.5, CEND1, SLC25A22, AP006621.6, PIDD1.
- chr11:837,356–867,116, 2 genes, copy number 5 (within-gene range 1–5): POLR2L, TSPAN4.
- chr12:65,134,688–68,745,809, 73 genes, copy number 7 (broad region; genes not listed).
- chr12:70,243,002–70,354,993, 2 genes, copy number 5 (within-gene range 3–5): CNOT2, AC092881.1.
- chr14:105,620,506–105,626,066, 2 genes, copy number 7–24: IGHG4, MIR8071-1.
- chr16:629,239–711,277, 17 genes, copy number 5–22 (within-gene range 4–22): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1.
- chr16:720,581–768,865, 5 genes, copy number 5–11: ANTKMT, CCDC78, HAGHL, CIAO3, MSLN.
- chr16:1,078,781–1,096,244, 2 genes, copy number 6–7: SSTR5, C1QTNF8.
- chr16:1,706,183–1,770,351, 3 genes, copy number 5 (within-gene range 0–5): MAPK8IP3, AL031710.2, AL031710.1.
- chr16:2,253,116–2,273,418, 4 genes, copy number 8: RNPS1, AC009065.4, MIR3677, MIR940.
- chr16:88,453,280–88,537,031, 3 genes, copy number 7–9: ZFPM1, MIR5189, AC116552.1.
- chr16:88,643,289–88,687,278, 4 genes, copy number 5 (within-gene range 4–5): CYBA, MVD, SNAI3-AS1, SNAI3.
- chr16:88,856,220–88,866,660, 2 genes, copy number 6 (within-gene range 4–6): TRAPPC2L, PABPN1L.
- chr19:1,248,553–1,279,244, 4 genes, copy number 6–15: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,573,596–1,592,865, 2 genes, copy number 5 (within-gene range 3–5): MBD3, AC005943.2.
- chr20:63,166,797–63,180,903, 2 genes, copy number 5: AL096828.1, MIR124-3.
- chr22:50,185,913–50,199,598, 2 genes, copy number 8 (within-gene range 0–13): TRABD, AL022328.3.

Autosomal genes at a single copy (total copy number 1): 875. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
